Somatic mutation profile of cancer-model specimen HCM-BROD-0129-C25-85C (3D Organoid, passage 10; aliquot HCM-BROD-0129-C25-85C-01D-A85K-36), derived from the primary tumor of HCMI case HCM-BROD-0129-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.0 years (27,748 days).
Specimen HCM-BROD-0129-C25-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82521183-4e18-46f8-9500-7bafb51b06ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0129-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0129-C25-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b224160e-af1b-495a-8c28-63d7b0e667ab

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Nonsense Mutation 3, 5'Flank 2, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 1398/1399 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 281/603 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 337/337 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 353/679 reads (52%) | catalogued as rs1461011219, COSV56567313; called by muse, mutect2, varscan2
- ARHGAP39 | c.2875C>A p.P959T (on ENST00000276826 / NM_001308208.2; = p.P990T on NM_025251.2) | Missense Mutation (SNP) | VAF 465/1009 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99431993; called by muse, mutect2, varscan2
- BCAS1 | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 373/811 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as COSV65085271; called by muse, mutect2, varscan2
- BRINP3 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 396/873 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66532334; called by muse, mutect2, varscan2
- DOCK10 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 238/495 reads (48%) | catalogued as rs1235207045, COSV51403973; called by muse, mutect2, varscan2
- DRICH1 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 284/895 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as COSV100497524; called by muse, mutect2, varscan2
- EZHIP | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 491/970 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as rs781990168, COSV100539509; called by muse, mutect2, varscan2
- FAM71A | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 406/858 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755100336, COSV54235975; called by muse, mutect2, varscan2
- FTCD | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 592/592 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as rs779047080; called by muse, mutect2, varscan2
- KIF3C | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 422/917 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV53100582; called by muse, mutect2, varscan2
- LRFN2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 440/872 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as COSV57827803; called by muse, mutect2, varscan2
- MGAT5B | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 331/331 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs751029852; called by muse, mutect2, varscan2
- MICB | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 1416/2151 reads (66%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs752321829, COSV52857666; called by muse, mutect2, varscan2
- NLGN4X | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 482/982 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as rs762832258, COSV52019787; called by muse, mutect2, varscan2
- NR1H3 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 413/796 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1165399959; called by muse, mutect2, varscan2
- OTOG | c.8269G>A p.G2757S | Missense Mutation (SNP) | VAF 358/808 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs764193229; called by muse, mutect2
- PCDHA4 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 496/1024 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as rs527429618; called by muse, varscan2
- RIPK4 | c.1687G>A p.G563R (on ENST00000352483; = p.G515R on NM_020639.3) | Missense Mutation (SNP) | VAF 503/505 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182590763; called by muse, mutect2, varscan2
- RSF1 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 413/795 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1374864792; called by muse, mutect2, varscan2
- TMEM132D | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 431/885 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs777663702, COSV70622617; called by muse, mutect2, varscan2
- WNK1 | c.3298C>T p.R1100W (on ENST00000315939 / NM_018979.4; = p.R853W on NM_014823.3) | Missense Mutation (SNP) | VAF 284/624 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750612826, COSV60043658; called by muse, mutect2, varscan2
- ZIC1 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 395/813 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.883); catalogued as rs759538522; called by muse, mutect2, varscan2
- ZKSCAN8 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 379/1219 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.1); catalogued as COSV57636806; called by muse, mutect2, varscan2
- ZZEF1 | c.6803A>G p.N2268S | Missense Mutation (SNP) | VAF 313/313 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs765601349; called by muse, mutect2, varscan2
- DGKB | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 285/680 reads (42%) | called by muse, mutect2, varscan2
- DNAH5 | c.4036dup p.Y1346Lfs*5 | Frame Shift Ins (INS) | VAF 203/513 reads (40%) | called by mutect2, pindel, varscan2
- EVI5L | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 492/1050 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FMO3 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 321/640 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- GRWD1 | c.962C>G p.P321R | Missense Mutation (SNP) | VAF 481/974 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- GZMH | c.694G>T p.V232F | Missense Mutation (SNP) | VAF 40/1005 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- MAP4K5 | c.2197C>A p.Q733K | Missense Mutation (SNP) | VAF 246/558 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- MUC5B | c.3622A>C p.N1208H | Missense Mutation (SNP) | VAF 344/753 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR8K1 | c.228T>A p.D76E | Missense Mutation (SNP) | VAF 483/1019 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PITPNB | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 486/773 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PLXNA3 | c.5128G>A p.D1710N | Missense Mutation (SNP) | VAF 403/946 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP2R5A | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 184/411 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RALGAPA1 | c.2890A>G p.I964V | Missense Mutation (SNP) | VAF 359/704 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ROCK2 | c.896T>G p.L299R | Missense Mutation (SNP) | VAF 227/452 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLX4 | c.5261A>G p.E1754G | Missense Mutation (SNP) | VAF 496/988 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SSR2 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 262/524 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TEX15 | c.862G>A p.E288K (on ENST00000638951; = p.E284K on NM_001350162.2) | Missense Mutation (SNP) | VAF 192/396 reads (48%) | SIFT tolerated (0.05); called by muse, mutect2, varscan2
- ZNF385A | c.598C>G p.L200V (on ENST00000338010 / NM_001130967.3; = p.L180V on NM_015481.3) | Missense Mutation (SNP) | VAF 440/883 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF589 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 213/436 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ZW10 | c.1376T>A p.M459K | Missense Mutation (SNP) | VAF 326/754 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCG4 | c.1449G>A p.P483= | Silent (SNP) | VAF 351/700 reads (50%) | catalogued as rs768914893; called by muse, mutect2, varscan2
- ATP6AP2 | c.51C>T p.N17= | Silent (SNP) | VAF 267/563 reads (47%) | catalogued as rs371701957; called by muse, mutect2, varscan2
- BOD1L1 | c.4467C>T p.G1489= | Silent (SNP) | VAF 376/759 reads (50%) | called by muse, mutect2, varscan2
- CHRM4 | c.561C>A p.I187= | Silent (SNP) | VAF 452/981 reads (46%) | called by muse, mutect2, varscan2
- CRX | c.564C>T p.S188= | Silent (SNP) | VAF 482/1013 reads (48%) | catalogued as rs148622001; called by muse, mutect2, varscan2
- FNDC1 | c.1818G>A p.T606= | Silent (SNP) | VAF 485/982 reads (49%) | catalogued as rs769365417, COSV51938999; called by muse, mutect2, varscan2
- KCNQ2 | c.2004G>A p.P668= (on ENST00000359125 / NM_172107.4; = p.P640= on NM_004518.6) | Silent (SNP) | VAF 578/1144 reads (51%) | catalogued as rs771807099, COSV100610430; called by muse, mutect2, varscan2
- KMO | c.1410C>T p.P470= | Silent (SNP) | VAF 325/698 reads (47%) | catalogued as rs150853900; called by muse, mutect2, varscan2
- MYH6 | c.5535C>T p.S1845= | Silent (SNP) | VAF 420/850 reads (49%) | catalogued as rs539962427; called by muse, mutect2, varscan2
- PCDH8 | c.399G>A p.P133= | Silent (SNP) | VAF 532/1104 reads (48%) | catalogued as COSV58811814; called by muse, mutect2, varscan2
- RBM10 | c.2319G>A p.A773= | Silent (SNP) | VAF 626/1290 reads (49%) | catalogued as rs781864232, COSV100238432; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHANK1 | c.4128G>A p.P1376= | Silent (SNP) | VAF 389/759 reads (51%) | called by muse, mutect2, varscan2
- SPECC1L | c.2496G>A p.S832= | Silent (SNP) | VAF 371/786 reads (47%) | catalogued as rs143996742; called by muse, mutect2, varscan2
- TBR1 | c.924A>G p.K308= | Silent (SNP) | VAF 277/577 reads (48%) | called by muse, varscan2
- TLR9 | c.1467G>A p.P489= | Silent (SNP) | VAF 453/928 reads (49%) | catalogued as rs760064176, COSV100645598; called by muse, mutect2, varscan2
- UNC13A | c.1179C>T p.T393= | Silent (SNP) | VAF 485/985 reads (49%) | catalogued as rs370189061; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823378 G>A | 5'Flank (SNP) | VAF 246/473 reads (52%) | called by muse, mutect2, varscan2
- KRAS | c.*107T>C | 3'UTR (SNP) | VAF 199/414 reads (48%) | catalogued as COSV55510905, COSV55732927; called by muse, mutect2, varscan2
- THSD4 | c.-80+14298C>T | Intron (SNP) | VAF 880/880 reads (100%) | catalogued as rs770443131; called by muse, mutect2, varscan2
- TRAPPC9 | chr8:140458456 G>A | 5'Flank (SNP) | VAF 802/1539 reads (52%) | called by muse, mutect2, varscan2
